Somatic mutation profile of tumor specimen TCGA-EM-A4FO-01A (aliquot TCGA-EM-A4FO-01A-11D-A257-08) from TCGA case TCGA-EM-A4FO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 72.8 years (26,589 days).
Specimen TCGA-EM-A4FO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c09f189-db7b-4f46-86d4-d42aceee2804.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FO-10A (Blood Derived Normal), aliquot TCGA-EM-A4FO-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/250fe8b3-e266-4adf-b31c-637fd63002e1

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOXL | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV61322003; called by muse, varscan2
- ATP1A2 | c.3004C>T p.R1002* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as rs1480634394, COSV63402340; called by muse, mutect2, varscan2
- BSG | c.213G>C p.W71C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61076216, COSV61076754; called by muse, mutect2
- DEGS2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.4); catalogued as rs184833633; called by muse, mutect2, varscan2
- OTUD5 | c.1417A>G p.M473V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs782366486, COSV50233888; called by muse, mutect2, varscan2
- PLCB1 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV62038905; called by muse, mutect2, varscan2
- RNF10 | c.1427A>G p.N476S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs756524465, COSV58043561; called by muse, mutect2, varscan2
- TMSB15A | c.29T>A p.V10E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782183922, COSV56818188; called by muse, mutect2, varscan2
- ZFYVE28 | c.1121G>C p.G374A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.368); catalogued as COSV52107695, COSV52110242; called by muse, mutect2, varscan2
- ENTPD6 | c.825C>T p.G275= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV61750941; called by muse, mutect2, varscan2
- NETO1 | c.1524C>T p.H508= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs144601570, COSV55007674; called by muse, mutect2, varscan2
- UBAP1 | c.420G>A p.T140= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1189858268, COSV52657359; called by muse, mutect2, varscan2
- STAG3L4 | n.554T>C | RNA (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
